Somatic mutation profile of tumor specimen TCGA-XF-A9ST-01A (aliquot TCGA-XF-A9ST-01A-11D-A42E-08) from TCGA case TCGA-XF-A9ST, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 68.7 years (25,080 days).
Specimen TCGA-XF-A9ST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79651476-977d-4203-bb41-4de12b4bdf4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9ST-10A (Blood Derived Normal), aliquot TCGA-XF-A9ST-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c78044-957f-4359-857e-f3a10286b6d9

The open-access MAF lists 624 somatic variants for this specimen: 477 protein-altering or splice-affecting, 133 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 389, Silent 133, Nonsense Mutation 30, Splice Site 26, Frame Shift Del 16, Splice Region 7, RNA 5, In Frame Del 5, 5'Flank 5, Intron 3, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 74/144 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV55540059, COSV55545034; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3017T>C p.M1006T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as COSV52743024; called by muse, mutect2, varscan2
- ABI3BP | c.2898T>G p.Y966* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99428417; called by muse, mutect2, varscan2
- AC005833.1 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); catalogued as COSV52896574; called by muse, mutect2, varscan2
- ACSBG2 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as rs1253734024, COSV53127269; called by muse, mutect2, varscan2
- ACSM2A | c.643G>A p.A215T (on ENST00000219054; = p.A136T on NM_001308169.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs759984727, COSV99525673; called by muse, mutect2, varscan2
- ACTA2 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV56516118; called by muse, mutect2, varscan2
- ACTR1A | c.189+1G>A p.X63_splice | Splice Site (SNP) | VAF 7/156 reads (4%) | catalogued as COSV64023146; called by muse, mutect2
- ADAM19 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV57427413; called by muse, mutect2, varscan2
- ADAM22 | c.1980A>C p.Q660H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV55974116; called by muse, mutect2, varscan2
- ADAMTS1 | c.859T>C p.S287P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53169716, COSV53170161; called by muse, mutect2, varscan2
- ADAMTS13 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63020180; called by muse, varscan2
- ADAMTS13 | c.1886G>C p.R629T | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV63020890; called by muse, varscan2
- ADAMTS14 | c.3380C>T p.P1127L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV64601204; called by muse, mutect2, varscan2
- ADGRF4 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV51951434; called by muse, mutect2, varscan2
- AFAP1L2 | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751236459, COSV58413863; called by muse, mutect2, varscan2
- AGA | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.046); catalogued as rs767103696, COSV52806051; called by muse, mutect2, varscan2
- AGRN | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1453057566, COSV65068894; called by muse, mutect2, varscan2
- AHSA1 | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV53631662; called by muse, mutect2, varscan2
- AKAP11 | c.4990C>G p.R1664G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV50295410, COSV99213574; called by muse, mutect2, varscan2
- ALDH1A2 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV51079725; called by muse, mutect2, varscan2
- ALOXE3 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750966729, COSV100503018, COSV58554639; called by muse, mutect2, varscan2
- ALYREF | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as COSV100485804, COSV58668374; called by muse, mutect2, varscan2
- AMER2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV63437031; called by muse, varscan2
- ANK3 | c.7933G>C p.E2645Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV55052535, COSV55087768; called by muse, mutect2, varscan2
- ANKRD10 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV57443303; called by muse, mutect2
- APIP | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV53506538; called by muse, mutect2, varscan2
- APLF | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100377035, COSV58143978; called by muse, mutect2, varscan2
- ARFGEF2 | c.3222G>C p.R1074S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64211712; called by muse, mutect2, varscan2
- ARHGAP26 | c.1433-1G>A p.X478_splice | Splice Site (SNP) | VAF 49/89 reads (55%) | catalogued as COSV50827484; called by muse, mutect2, varscan2
- ARID5B | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54418042; called by muse, mutect2, varscan2
- ARL8B | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV56577721; called by muse, mutect2, varscan2
- ARRB1 | c.619-1G>A p.X207_splice | Splice Site (SNP) | VAF 27/153 reads (18%) | catalogued as COSV63575037; called by muse, mutect2, varscan2
- ARRDC3 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV99475389; called by muse, mutect2, varscan2
- ART3 | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61913765; called by muse, mutect2, varscan2
- ASAP1 | c.2161C>G p.L721V | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1331757574, COSV63047119; called by muse, mutect2
- ASAP2 | c.1599G>C p.R533S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV55629800; called by muse, mutect2, varscan2
- ATN1 | c.1577A>G p.H526R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.66); catalogued as COSV63110733; called by muse, mutect2, varscan2
- ATP1A2 | c.1830G>A p.V610= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV63403286; called by mutect2, varscan2
- ATP6V0A4 | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV59474438, COSV59481098; called by muse, mutect2
- ATR | c.3522G>T p.M1174I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.208); catalogued as rs1431589305, COSV63385562; called by muse, mutect2, varscan2
- B4GALNT4 | c.3018G>T p.E1006D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs766808864, COSV57322663; called by muse, mutect2, varscan2
- BBS4 | c.1451-1G>T p.X484_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99166529; called by muse, mutect2, varscan2
- BCAR3 | c.1770C>G p.H590Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV53074116; called by muse, mutect2, varscan2
- BHMT2 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs1212923178, COSV54872400; called by muse, mutect2, varscan2
- BICDL1 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57493070; called by muse, mutect2, varscan2
- BMP5 | c.1104+2T>C p.X368_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV63702436; called by muse, mutect2, varscan2
- BPIFB4 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100971654; called by muse, mutect2, varscan2
- BRD2 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV66372992; called by muse, mutect2, varscan2
- BRD2 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV66372996; called by muse, mutect2, varscan2
- BRSK1 | c.726G>C p.K242N | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58665791; called by muse, mutect2, varscan2
- BSCL2 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV54015259; called by muse, mutect2, varscan2
- BTN3A1 | c.85+2T>A p.X29_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as COSV50024639, COSV50024875; called by muse, mutect2, varscan2
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C16orf70 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54626787; called by muse, mutect2, varscan2
- C18orf25 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | catalogued as COSV99960198; called by muse, mutect2, varscan2
- C20orf194 | c.1030T>C p.Y344H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs368185350; called by muse, mutect2, varscan2
- C5 | c.4240G>C p.E1414Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56326132, COSV99797588; called by muse, mutect2, varscan2
- CAB39 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV51475518, COSV51476115; called by muse, mutect2, varscan2
- CACNG3 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50065936, COSV50070650; called by muse, mutect2, varscan2
- CACNG4 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.827); catalogued as rs199939691, COSV50924634; called by mutect2, varscan2
- CALD1 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.771); catalogued as COSV62646914; called by muse, mutect2, varscan2
- CASQ1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63624028; called by muse, mutect2, varscan2
- CCDC106 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs201897477, COSV54401611; called by muse, mutect2, varscan2
- CCDC141 | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV55369931, COSV55371854; called by muse, mutect2, varscan2
- CCDC82 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV53592918; called by muse, varscan2
- CCHCR1 | c.535-2A>C p.X179_splice | Splice Site (SNP) | VAF 33/129 reads (26%) | catalogued as COSV66183414; called by muse, mutect2, varscan2
- CCKBR | c.838del p.R280Gfs*27 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV58102797; called by mutect2, pindel, varscan2
- CD180 | c.12C>G p.D4E | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0.02); catalogued as COSV56517550, COSV99842374; called by muse, mutect2, varscan2
- CD1D | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.196); catalogued as COSV63808795; called by muse, mutect2, varscan2
- CDC20 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV60521984; called by muse, mutect2, varscan2
- CDH19 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 100/169 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0.266); catalogued as rs755888839, COSV50956786; called by muse, mutect2, varscan2
- CDH6 | c.2072A>G p.D691G | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs931815834, COSV54067724; called by muse, mutect2, varscan2
- CENPE | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1305864083, COSV99479006; called by muse, mutect2, varscan2
- CEP104 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as COSV65516804; called by muse, mutect2, varscan2
- CEP192 | c.6280G>C p.G2094R | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as COSV58062536; called by muse, mutect2, varscan2
- CEP70 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs748990528, COSV53875091; called by muse, mutect2, varscan2
- CHAF1B | c.1301C>G p.P434R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs1380725465, COSV58439735; called by muse, mutect2, varscan2
- CHCHD10 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100533711; called by muse, mutect2
- CHRNB4 | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747045440, COSV55715592; called by muse, mutect2, varscan2
- CKM | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55532641; called by muse, mutect2, varscan2
- CKS2 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1185918993, COSV58686346; called by muse, mutect2, varscan2
- CLEC16A | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV68499109; called by muse, mutect2, varscan2
- CLPTM1L | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1314199327, COSV57990085; called by muse, mutect2, varscan2
- CNNM1 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV63201192; called by muse, mutect2, varscan2
- CNOT4 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV59651334; called by muse, mutect2, varscan2
- CNTNAP1 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.226); catalogued as COSV52849285; called by muse, mutect2, varscan2
- CNTRL | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53045701; called by muse, mutect2, varscan2
- COL1A1 | c.1787G>C p.G596A | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402406091, CD138588, COSV99868055; called by muse, mutect2, varscan2
- COL1A1 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM930140, COSV56803737, COSV56809422; called by muse, mutect2, varscan2
- COL22A1 | c.3831C>G p.F1277L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.982); catalogued as COSV57332027; called by muse, mutect2
- COL24A1 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV65304769; called by muse, mutect2, varscan2
- COL6A5 | c.7249G>A p.E2417K (on ENST00000312481; = p.E2413K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs368502118; called by muse, mutect2, varscan2
- COLEC12 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV68369925; called by muse, mutect2, varscan2
- CPA4 | c.68+1G>A p.X23_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as rs1562926594, COSV55979179; called by muse, mutect2, varscan2
- CRNKL1 | c.1930A>T p.I644F | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV66105686; called by muse, mutect2, varscan2
- CRTC2 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57842039; called by muse, mutect2, varscan2
- CSDE1 | c.2267G>C p.R756P (on ENST00000358528 / NM_001007553.3; = p.R725P on NM_007158.6) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV54736408, COSV54743622; called by muse, mutect2, varscan2
- CUBN | c.8702T>A p.V2901D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.825); catalogued as COSV64713092; called by muse, mutect2, varscan2
- CYB561A3 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565633437, COSV53651485; called by muse, mutect2, varscan2
- DAAM1 | c.1259A>G p.Q420R | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV62835577; called by muse, mutect2, varscan2
- DAXX | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56468271; called by muse, mutect2, varscan2
- DBR1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53429441; called by muse, mutect2, varscan2
- DCC | c.1431G>T p.L477F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as rs1300510190, COSV100499766, COSV59096757; called by muse, mutect2, varscan2
- DCUN1D2 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60261074; called by muse, mutect2, varscan2
- DENND1C | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV57568350; called by muse, mutect2, varscan2
- DHX40 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as COSV52066949; called by muse, mutect2, varscan2
- DIDO1 | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 74/80 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56618766; called by muse, mutect2, varscan2
- DNAAF1 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | catalogued as COSV100499781; called by muse, mutect2, varscan2
- DNAH10 | c.3711G>T p.K1237N (on ENST00000409039; = p.K1176N on NM_207437.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101292632; called by muse, mutect2, varscan2
- DNAH8 | c.2142G>C p.L714F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as rs1208591601, COSV100547102; called by muse, mutect2
- DNAJB5 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56625258; called by muse, mutect2, varscan2
- DNAJC13 | c.3944A>G p.H1315R | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV53448857; called by muse, mutect2, varscan2
- DOCK10 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.43); catalogued as rs1328372770, COSV51371522; called by muse, mutect2, varscan2
- DOP1A | c.5738C>T p.P1913L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52708946; called by muse, mutect2, varscan2
- DOP1B | c.4540G>A p.G1514S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as rs370428535; called by muse, mutect2, varscan2
- DOT1L | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV67109059; called by muse, mutect2, varscan2
- DRD5 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV58577570; called by muse, mutect2, varscan2
- DSCAML1 | c.2173G>C p.G725R (on ENST00000321322; = p.G665R on NM_020693.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58387759; called by muse, mutect2, varscan2
- DSG4 | c.3074C>A p.S1025Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1376598112, COSV57390354; called by muse, mutect2, varscan2
- DST | c.19823T>C p.M6608T (on ENST00000361203 / NM_001374722.1; = p.M4305T on NM_015548.5) | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs763176568, COSV55008085; called by muse, mutect2, varscan2
- DTX3L | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV56143882; called by muse, mutect2, varscan2
- DUSP6 | c.461C>G p.S154W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs752316502, COSV99684136; called by muse, varscan2
- DYNC2H1 | c.12190C>G p.P4064A | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV62091425, COSV62092381; called by muse, mutect2, varscan2
- EEF2K | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.74); catalogued as COSV53780533; called by muse, mutect2, varscan2
- EFNB2 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55364324, COSV55365093; called by muse, mutect2, varscan2
- EGFLAM | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV59298340, COSV59313843; called by muse, mutect2, varscan2
- ELAVL3 | c.486A>T p.T162= | Splice Region (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63645577; called by muse, mutect2, varscan2
- ENTHD1 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1330947654, COSV57319029; called by muse, mutect2, varscan2
- ENTR1 | c.313G>A p.E105K (on ENST00000357365 / NM_001039707.2; = p.E82K on NM_006643.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53741165; called by muse, mutect2, varscan2
- EPG5 | c.5038G>C p.V1680L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56347985; called by muse, mutect2, varscan2
- ESPL1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV57758694; called by muse, mutect2, varscan2
- EXD1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV59253288, COSV59255551; called by muse, mutect2, varscan2
- FABP2 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV56788370; called by muse, mutect2, varscan2
- FAM151A | c.1595C>A p.S532Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56363661, COSV56364328, COSV56366172; called by muse, mutect2, varscan2
- FAM160B1 | c.2192+2del p.X731_splice | Splice Site (DEL) | VAF 17/71 reads (24%) | catalogued as COSV65087830; called by mutect2, pindel, varscan2
- FAM166A | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100457946, COSV61116243; called by muse, mutect2, varscan2
- FAM184A | c.2916-1G>A p.X972_splice | Splice Site (SNP) | VAF 24/44 reads (55%) | catalogued as rs1212480684, COSV58852123, COSV58853336; called by muse, mutect2, varscan2
- FAM219B | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV62946798; called by muse, mutect2, varscan2
- FAM221B | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65074156; called by muse, mutect2, varscan2
- FANCA | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV66881165; called by muse, mutect2, varscan2
- FAT3 | c.22T>C p.C8R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1207209525, COSV53097453, COSV53111356; called by muse, mutect2, varscan2
- FBLN2 | c.1754G>C p.R585P | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV55483030, COSV55484517; called by muse, mutect2, varscan2
- FBXO48 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58143365, COSV58143970; called by muse, mutect2, varscan2
- FGF5 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as COSV56889682; called by muse, mutect2, varscan2
- FHL5 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781249992, COSV58736869; called by muse, mutect2, varscan2
- FLAD1 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as COSV52696529; called by muse, mutect2, varscan2
- FMO3 | c.631A>T p.M211L | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63006938; called by muse, mutect2, varscan2
- FNDC3A | c.3002A>G p.Y1001C (on ENST00000492622 / NM_001079673.2; = p.Y945C on NM_014923.5) | Missense Mutation (SNP) | VAF 62/64 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764297443, COSV68132746; called by muse, mutect2, varscan2
- FOXR2 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100189606; called by muse, mutect2, varscan2
- FRRS1 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV54921605; called by muse, mutect2, varscan2
- GABRA4 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV51923253; called by muse, mutect2, varscan2
- GAPT | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59246842, COSV59247312; called by muse, mutect2, varscan2
- GDF9 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51526068; called by muse, mutect2, varscan2
- GHR | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV50109868; called by muse, mutect2, varscan2
- GINS4 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV52531236; called by muse, mutect2, varscan2
- GLI1 | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV57360497, COSV99953797; called by muse, mutect2, varscan2
- GOLGA5 | c.1320+2T>G p.X440_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV50832603; called by muse, mutect2, varscan2
- GPAM | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1216263555, COSV62080734; called by muse, mutect2, varscan2
- GPR142 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV59519089; called by muse, mutect2, varscan2
- GRIA4 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56890545; called by muse, mutect2, varscan2
- GRIK2 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.791); catalogued as COSV59727959; called by muse, mutect2, varscan2
- GRM5 | c.2719A>G p.M907V | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV59600165; called by muse, mutect2, varscan2
- H2BC5 | c.346A>T p.T116S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV56800589; called by muse, mutect2, varscan2
- H2BC7 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV61911790, COSV61912523; called by muse, mutect2, varscan2
- H3-3B | c.316del p.E106Kfs*33 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | catalogued as COSV54665444, COSV54665858, COSV54666236; called by mutect2, pindel, varscan2
- H3C2 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52518397, COSV52518528; called by muse, mutect2
- HARBI1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs577458840, COSV56318633; called by muse, mutect2, varscan2
- HDC | c.728C>A p.A243E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142761358, COSV51069310; called by muse, mutect2, varscan2
- HEATR5A | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66339670; called by muse, mutect2, varscan2
- HECW2 | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV53655616; called by muse, mutect2, varscan2
- HERC2 | c.3803A>G p.E1268G | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV55317958; called by muse, mutect2, varscan2
- HIVEP1 | c.5965C>T p.L1989F | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.16); catalogued as COSV65100409; called by muse, mutect2, varscan2
- HK1 | c.1893C>G p.H631Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53856345; called by muse, mutect2, varscan2
- HMGB1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV58104539; called by muse, mutect2
- HNRNPU | c.1673A>T p.N558I (on ENST00000283179; = p.N620I on NM_004501.3) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.414); catalogued as COSV51690470; called by muse, mutect2, varscan2
- HOXA9 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58656010, COSV58656017, COSV58656626; called by muse, mutect2
- HSD17B4 | c.2007G>T p.K669N (on ENST00000414835 / NM_001199291.3; = p.K644N on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV56334865; called by muse, mutect2, varscan2
- HSPA4 | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV59182180; called by muse, mutect2, varscan2
- HSPA5 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV52334901; called by muse, mutect2, varscan2
- HSPA5 | c.1504G>C p.E502Q | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV99413617; called by muse, mutect2, varscan2
- HTR6 | c.1024C>G p.R342G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53871649; called by mutect2, varscan2
- HUNK | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs576162040, COSV54225776; called by muse, mutect2, varscan2
- IFI16 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99858131; called by muse, mutect2, varscan2
- IFNAR2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99270146; called by muse, mutect2, varscan2
- IGSF3 | c.1221C>A p.L407= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as COSV59589162; called by muse, mutect2, varscan2
- IGSF9B | c.2098A>T p.I700F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV58066232; called by muse, mutect2, varscan2
- IMPG2 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs567713065, COSV51976397; called by muse, mutect2, varscan2
- INSRR | c.2887G>A p.A963T | Missense Mutation (SNP) | VAF 105/153 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs763193926, COSV63870909; called by muse, mutect2, varscan2
- INTS14 | c.281G>A p.G94D (on ENST00000313182 / NM_001366360.2; = p.G15D on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV57526579; called by muse, mutect2, varscan2
- IRAK4 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV71210373; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1153G>A p.D385N (on ENST00000439118 / NM_001008949.3; = p.D393N on NM_178495.6) | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs982857512, COSV63153030; called by muse, mutect2, varscan2
- JAG1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV54755633; called by muse, mutect2
- JMJD6 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV57971303; called by muse, mutect2, varscan2
- KANK4 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.086); catalogued as rs770542008, COSV62986164; called by muse, mutect2, varscan2
- KCND2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576011; called by muse, mutect2, varscan2
- KCNJ12 | c.1012T>A p.Y338N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59165703; called by muse, mutect2, varscan2
- KCNT1 | c.3446C>T p.A1149V (on ENST00000488444; = p.A1130V on NM_001272003.2) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as COSV53699529; called by muse, mutect2, varscan2
- KCTD16 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV72578208; called by muse, mutect2, varscan2
- KCTD19 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV58572199; called by muse, mutect2, varscan2
- KCTD4 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 122/136 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV61238940; called by muse, mutect2, varscan2
- KDM1A | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63087468; called by muse, mutect2, varscan2
- KDM2B | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV65639620; called by muse, mutect2, varscan2
- KDR | c.671A>T p.Y224F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV55762234, COSV55769733; called by muse, mutect2, varscan2
- KIDINS220 | c.3350C>T p.S1117L | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV56752180; called by muse, mutect2, varscan2
- KLRF1 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1405446335, COSV54380657; called by muse, mutect2, varscan2
- KNTC1 | c.2225G>A p.R742K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV61079630; called by muse, mutect2
- KRT79 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57939400; called by muse, mutect2, varscan2
- KRTAP10-7 | c.672C>G p.C224W | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV59109978; called by muse, varscan2
- LAMB1 | c.3080-1G>C p.X1027_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55971922; called by muse, mutect2
- LAMC1 | c.4129G>C p.V1377L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.631); catalogued as COSV51137413, COSV51141679; called by muse, mutect2, varscan2
- LDB2 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 21/23 reads (91%) | catalogued as rs771669555, COSV58763457; called by muse, mutect2, varscan2
- LHB | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55484822; called by muse, mutect2, varscan2
- LMAN1 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV51826521; called by muse, mutect2, varscan2
- LMOD1 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100939303, COSV66172359; called by muse, mutect2, varscan2
- LRIT3 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CM130262, COSV59984490; called by muse, mutect2, varscan2
- LRIT3 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV59984514; called by muse, mutect2, varscan2
- LRP1 | c.5513A>C p.E1838A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV54507568; called by muse, mutect2
- LRRC37A3 | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58534914; called by muse, mutect2, varscan2
- LRRCC1 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV64483141; called by muse, mutect2, varscan2
- LTV1 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367844998; called by muse, mutect2, varscan2
- MACO1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV65475131, COSV65476102; called by muse, mutect2, varscan2
- MAGEL2 | c.1931A>T p.Q644L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100046190; called by muse, mutect2
- MAGI2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as rs777063252, COSV62645997; called by muse, mutect2, varscan2
- MAK | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57564894; called by muse, mutect2, varscan2
- MAL | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV59431018, COSV59431234; called by muse, mutect2, varscan2
- MAP3K9 | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV67120820; called by muse, mutect2, varscan2
- MAPK11 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV57996802; called by muse, mutect2, varscan2
- MAPRE1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV65032699; called by muse, mutect2, varscan2
- MAST1 | c.3338C>G p.S1113W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52244715; called by muse, mutect2
- MBD1 | c.1030T>A p.C344S (on ENST00000269468 / NM_001323950.1; = p.C321S on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54000016; called by muse, mutect2, varscan2
- MCHR1 | c.1173G>C p.L391F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV50760897; called by muse, mutect2, varscan2
- MDM2 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV50698650; called by muse, mutect2, varscan2
- MDN1 | c.16549C>G p.R5517G | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV65520202, COSV65528740; called by muse, mutect2, varscan2
- MEGF11 | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99989113; called by muse, mutect2, varscan2
- MGAT2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 37/63 reads (59%) | catalogued as COSV100023635; called by muse, mutect2, varscan2
- MMP27 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as rs148894063, COSV52780410; called by muse, mutect2, varscan2
- MPHOSPH9 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 77/121 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56618498; called by muse, mutect2, varscan2
- MROH9 | c.957C>G p.I319M | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63010803; called by muse, mutect2, varscan2
- MRPS18B | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.856); catalogued as COSV52541270; called by muse, mutect2, varscan2
- MTMR2 | c.697C>G p.R233G | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60579238, COSV60581294; called by muse, mutect2, varscan2
- MVB12B | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 55/79 reads (70%) | catalogued as rs1254051514, COSV63259414; called by muse, mutect2, varscan2
- MYCBP2 | c.13320C>G p.C4440W (on ENST00000357337; = p.C4478W on NM_015057.5) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62015125; called by muse, mutect2, varscan2
- MYCBP2 | c.4582G>A p.D1528N (on ENST00000357337; = p.D1566N on NM_015057.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62015135; called by muse, mutect2
- MYO15A | c.8813G>C p.G2938A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV52754991; called by muse, mutect2, varscan2
- MYO19 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs761442578; called by muse, mutect2
- MYOM3 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV100293771; called by muse, mutect2, varscan2
- NECTIN3 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs763550976, COSV60550685; called by muse, mutect2, varscan2
- NEGR1 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV60840264; called by muse, mutect2, varscan2
- NEK6 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 103/154 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV57216929; called by muse, mutect2, varscan2
- NEK8 | c.1893G>A p.E631= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as rs746222138, COSV52044273; called by muse, mutect2, varscan2
- NES | c.2714C>G p.S905C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs772116906, COSV63960731; called by muse, mutect2, varscan2
- NKG7 | c.439+1G>A p.X147_splice | Splice Site (SNP) | VAF 32/60 reads (53%) | catalogued as COSV52467344; called by muse, mutect2, varscan2
- NLK | c.1095G>C p.M365I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV63490573; called by muse, mutect2
- NLRP7 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV60172924; called by muse, mutect2, varscan2
- NPC1 | c.2988G>A p.M996I | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1174061971, COSV52577887; called by muse, varscan2
- NUP188 | c.1974G>A p.M658I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV65360238; called by muse, mutect2, varscan2
- ODAM | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV68572610; called by muse, mutect2, varscan2
- OGA | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as COSV63381423; called by muse, mutect2, varscan2
- OR14I1 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs147758863; called by muse, mutect2, varscan2
- OR2H1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 92/158 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs765023977, COSV65810173; called by muse, mutect2, varscan2
- OR2J3 | c.827T>A p.F276Y | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs763336423, COSV65848903; called by muse, mutect2, varscan2
- OR52I1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV56168185; called by muse, mutect2, varscan2
- OR5V1 | c.411C>G p.S137R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65827262; called by muse, mutect2, varscan2
- OR7C2 | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV50180418; called by muse, mutect2, varscan2
- OR8K1 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV54402096; called by muse, mutect2, varscan2
- OSBPL9 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.149); catalogued as rs769698097, COSV61868462; called by muse, mutect2, varscan2
- OSM | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53161114; called by muse, mutect2, varscan2
- OTC | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50001190; called by muse, mutect2, varscan2
- P2RX2 | c.390G>C p.R130S (on ENST00000343948 / NM_170683.4; = p.R106S on NM_016318.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.068); catalogued as COSV57678051; called by muse, mutect2
- PADI3 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100968592; called by muse, mutect2, varscan2
- PALMD | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54163936; called by muse, mutect2, varscan2
- PAPPA | c.3874C>G p.Q1292E | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1220683574, COSV60280949; called by muse, mutect2, varscan2
- PARD3 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1199321504, COSV60747993, COSV60749082; called by muse, mutect2, varscan2
- PCDHB3 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV50568700; called by muse, mutect2, varscan2
- PCNT | c.6341C>T p.S2114F | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV64026937; called by muse, mutect2, varscan2
- PCSK6 | c.383T>C p.F128S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV60166569; called by muse, mutect2, varscan2
- PDE4A | c.895G>T p.E299* (on ENST00000380702 / NM_001111307.2; = p.E60* on NM_006202.3) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99535110; called by muse, mutect2, varscan2
- PDIA5 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60248415; called by muse, mutect2, varscan2
- PDSS2 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.138); catalogued as COSV64654306; called by muse, mutect2, varscan2
- PDSS2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs769947770, COSV64647394; called by muse, mutect2, varscan2
- PDZRN3 | c.2041G>T p.V681L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs753757339, COSV55196217; called by muse, mutect2, varscan2
- PFAS | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV58979548; called by muse, mutect2, varscan2
- PHF10 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as COSV59321707; called by muse, mutect2, varscan2
- PIBF1 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV58322116, COSV58328331; called by muse, mutect2, varscan2
- PLA2G4A | c.1941C>G p.F647L | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66553232; called by muse, mutect2, varscan2
- PLCD4 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV68842408; called by muse, mutect2, varscan2
- PLEKHG4B | c.3341G>A p.R1114K (on ENST00000283426; = p.R1470K on NM_052909.5) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769648412, COSV52046023; called by muse, mutect2
- PLPBP | c.334T>G p.F112V | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV60239545; called by muse, mutect2, varscan2
- PLPP3 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV64839153; called by muse, mutect2, varscan2
- PMPCB | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV50785786; called by muse, mutect2, varscan2
- PNLIPRP1 | c.476G>C p.S159T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100724477, COSV62611408; called by muse, mutect2, varscan2
- POLQ | c.2401T>G p.L801V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV51749470; called by muse, mutect2, varscan2
- POPDC3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV54643635, COSV54643704, COSV54644363; called by muse, mutect2, varscan2
- PPIG | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as COSV53642387, COSV99644912; called by muse, mutect2, varscan2
- PPM1D | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV59955188, COSV59955490; called by muse, mutect2, varscan2
- PPM1F | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1174030342, COSV54283742; called by muse, mutect2, varscan2
- PPP5C | c.936C>G p.I312M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV99183659; called by muse, mutect2
- PRAM1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs1421385286, COSV99725851; called by muse, mutect2
- PRAME | c.649G>C p.A217P | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV67161343; called by muse, mutect2, varscan2
- PRDX4 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 21/23 reads (91%) | catalogued as COSV101026763; called by muse, mutect2, varscan2
- PRICKLE3 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99603080; called by muse, mutect2, varscan2
- PRKCB | c.1538T>A p.I513N | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57774350; called by muse, mutect2, varscan2
- PRKCH | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs755198845, COSV60647393; called by muse, mutect2, varscan2
- PRKG1 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as COSV64768197; called by muse, mutect2, varscan2
- PRPH | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV57678346; called by muse, mutect2, varscan2
- PSD | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.893); catalogued as rs757230181, COSV50044152; called by muse, mutect2, varscan2
- PSG4 | c.1097G>A p.W366* | Nonsense Mutation (SNP) | VAF 37/131 reads (28%) | catalogued as COSV99737785; called by muse, mutect2, varscan2
- PSG8 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1239842104, COSV100126318, COSV60610870; called by muse, mutect2, varscan2
- PSMG1 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV59000234; called by muse, mutect2, varscan2
- PTPRD | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 58/67 reads (87%) | catalogued as COSV100646674, COSV61975384; called by muse, mutect2, varscan2
- PTX3 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV55821493; called by muse, mutect2, varscan2
- PURB | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67480238; called by mutect2, varscan2
- QDPR | c.645G>C p.W215C | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55549766; called by muse, mutect2, varscan2
- QKI | c.286-2A>C p.X96_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as rs1409696271, COSV51692188; called by muse, mutect2, varscan2
- R3HCC1L | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV54400495; called by muse, mutect2, varscan2
- RAB5C | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as COSV60524857; called by muse, mutect2, varscan2
- RAD50 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534015582, COSV54750016, COSV99529639; called by muse, mutect2, varscan2
- RAI1 | c.1693T>C p.S565P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55391820; called by muse, mutect2, varscan2
- RAP2C | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs770378656, COSV61683307; called by muse, mutect2, varscan2
- RASGEF1B | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1441258181, COSV100021061, COSV52336607; called by muse, mutect2, varscan2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 46/52 reads (88%) | catalogued as COSV57297594; called by mutect2, varscan2
- RBM23 | c.558C>A p.F186L (on ENST00000359890 / NM_001077351.2; = p.F170L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57127355; called by muse, mutect2, varscan2
- RECK | c.2090C>A p.T697K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV65035082; called by muse, mutect2, varscan2
- REG3A | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59409150; called by muse, mutect2, varscan2
- RETREG2 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs766442504, COSV56087353, COSV99811680; called by muse, mutect2, varscan2
- RGS18 | c.102C>G p.S34R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as rs776818634, COSV66507738; called by muse, mutect2, varscan2
- RHOT1 | c.1436C>A p.S479* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs368654873, COSV100447587; called by muse, mutect2, varscan2
- RNF121 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as COSV52620435; called by muse, mutect2, varscan2
- RNF138 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV55233938, COSV55234617; called by muse, mutect2, varscan2
- RNF17 | c.4448-2A>G p.X1483_splice | Splice Site (SNP) | VAF 42/85 reads (49%) | catalogued as rs1465699792, COSV55038105; called by muse, mutect2, varscan2
- ROM1 | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53881981; called by muse, mutect2, varscan2
- RPS2 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs777377021, COSV99238919; called by muse, mutect2, varscan2
- RTN4 | c.614-1G>A p.X205_splice | Splice Site (SNP) | VAF 19/29 reads (66%) | catalogued as COSV58266421; called by muse, mutect2, varscan2
- RTP5 | c.1214T>A p.L405Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as COSV58319554; called by muse, mutect2, varscan2
- RUFY3 | c.570C>G p.L190= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56913605; called by muse, mutect2
- S1PR4 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV55739938; called by muse, mutect2, varscan2
- SAXO1 | c.39-1G>A p.X13_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV65869687; called by muse, mutect2, varscan2
- SCUBE2 | c.2174-1G>A p.X725_splice (on ENST00000649792 / NM_001367977.2; = p.X668_splice on NM_020974.3) | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100496919; called by muse, mutect2
- SEC23B | c.835-1G>A p.X279_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV52719640; called by muse, mutect2, varscan2
- SELP | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.844); catalogued as COSV55247746; called by muse, mutect2, varscan2
- SEMA3E | c.1570A>G p.S524G | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV57085885; called by muse, mutect2, varscan2
- SEMA4G | c.2456G>C p.R819P (on ENST00000370250; = p.R824P on NM_017893.3) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52967334, COSV52971292; called by muse, mutect2, varscan2
- SEMA5B | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.282); catalogued as COSV52095300; called by muse, mutect2, varscan2
- SETD2 | c.7684G>A p.E2562K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57435095; called by muse, mutect2, varscan2
- SETD2 | c.2134A>G p.K712E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as rs1425661679, COSV57435107, COSV57455196; called by muse, mutect2, varscan2
- SF3B5 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV62451238; called by muse, mutect2, varscan2
- SGPL1 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs1436507911, COSV64591395; called by muse, mutect2, varscan2
- SGSM2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52157187; called by muse, mutect2, varscan2
- SHMT2 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV61073688; called by muse, mutect2, varscan2
- SHOC1 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.215); catalogued as COSV59499800; called by muse, mutect2, varscan2
- SHOC2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1362516887, COSV54620962; called by muse, mutect2
- SIK3 | c.2728G>A p.D910N (on ENST00000445177 / NM_001366686.2; = p.D868N on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV52612310; called by muse, mutect2, varscan2
- SIPA1L2 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768801084, COSV53388173; called by muse, mutect2, varscan2
- SIRT6 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50183519; called by muse, mutect2, varscan2
- SLC25A16 | c.606T>G p.Y202* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99770256; called by muse, mutect2, varscan2
- SLC28A3 | c.1449+2T>C p.X483_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100883334; called by muse, mutect2, varscan2
- SLC2A4RG | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.399); catalogued as rs754968808, COSV55508712; called by muse, mutect2, varscan2
- SLC35D1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs768719387, COSV52430915; called by muse, mutect2, varscan2
- SLC38A4 | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV56966573; called by muse, mutect2, varscan2
- SLC6A14 | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV64140950; called by muse, mutect2, varscan2
- SLC6A4 | c.1112C>G p.T371R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99911579; called by muse, mutect2
- SLC6A4 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as CM057895, COSV55566214; called by muse, mutect2, varscan2
- SLCO1C1 | c.105del p.K35Nfs*8 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV56871047, COSV56876472, COSV99859972; called by mutect2, pindel, varscan2
- SLCO1C1 | c.507del p.K169Nfs*6 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | catalogued as COSV99858431; called by mutect2, pindel, varscan2
- SMARCD1 | c.1269G>A p.K423= | Splice Region (SNP) | VAF 21/64 reads (33%) | catalogued as COSV67411906; called by muse, mutect2, varscan2
- SMC2 | c.2957G>C p.R986T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV53956893; called by muse, mutect2, varscan2
- SMC3 | c.2471T>C p.I824T | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV62419690; called by muse, mutect2, varscan2
- SNX14 | c.2537C>T p.S846L (on ENST00000314673 / NM_001350535.1; = p.S793L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV59011125, COSV59013532; called by muse, mutect2, varscan2
- SOX6 | c.2452G>T p.E818* (on ENST00000528429 / NM_001145819.2; = p.E791* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100323164; called by muse, mutect2, varscan2
- SPANXN2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.946); catalogued as COSV65128180; called by muse, mutect2, varscan2
- SPARC | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50558167, COSV50558399; called by muse, mutect2, varscan2
- SPHK2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs762850900, COSV55336411; called by muse, mutect2, varscan2
- SPTA1 | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs748582690, COSV63749388, COSV63751553; called by muse, mutect2, varscan2
- SRGAP2 | c.3044G>T p.G1015V (on ENST00000624873 / NM_001170637.4; = p.G1016V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV55335757; called by muse, mutect2, varscan2
- SRP54 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.343); catalogued as rs1285684867, COSV53738481; called by muse, mutect2, varscan2
- ST6GAL2 | c.655_669del p.P219_K223del | In Frame Del (DEL) | VAF 9/13 reads (69%) | catalogued as COSV64527584; called by mutect2, varscan2
- STAC2 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV61065143; called by muse, mutect2, varscan2
- STAC3 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 184/463 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60413878; called by muse, mutect2, varscan2
- STAG2 | c.1927_1937del p.E643Lfs*14 | Frame Shift Del (DEL) | VAF 20/24 reads (83%) | catalogued as COSV54355770; called by mutect2, pindel, varscan2
- STK36 | c.1672C>G p.Q558E | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55325632; called by muse, varscan2
- STK36 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV55325649; called by muse, varscan2
- STK36 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 27/32 reads (84%) | catalogued as COSV99831901; called by muse, mutect2, varscan2
- SUGT1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV59421549; called by muse, mutect2, varscan2
- SYBU | c.740C>G p.S247C (on ENST00000276646 / NM_001099754.2; = p.S246C on NM_017786.6) | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV52616421; called by muse, mutect2, varscan2
- TAOK1 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55590461; called by muse, mutect2, varscan2
- TAS1R3 | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV59562929; called by muse, mutect2, varscan2
- TCP11L2 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54429655; called by muse, mutect2, varscan2
- TDRKH | c.1281A>C p.S427= | Splice Region (SNP) | VAF 49/318 reads (15%) | catalogued as COSV58617905; called by muse, mutect2, varscan2
- TEAD3 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58816298; called by muse, mutect2, varscan2
- TENT5C | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65616245; called by muse, mutect2, varscan2
- TESK1 | c.1413G>C p.E471D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV52410779; called by muse, mutect2, varscan2
- TFB2M | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63620209; called by muse, mutect2, varscan2
- TFDP2 | c.664-1G>A p.X222_splice (on ENST00000489671 / NM_001178139.2; = p.X162_splice on NM_006286.5) | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV57706698; called by muse, mutect2, varscan2
- TFF2 | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV99367219; called by mutect2, varscan2
- TG | c.6262+2T>A p.X2088_splice | Splice Site (SNP) | VAF 23/123 reads (19%) | catalogued as COSV55072259; called by muse, mutect2, varscan2
- TIAM2 | c.1931T>G p.L644R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV59692620; called by muse, mutect2, varscan2
- TIE1 | c.2682G>T p.L894F | Missense Mutation (SNP) | VAF 102/142 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65249207; called by muse, mutect2, varscan2
- TIGD2 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs752623482, COSV57647316, COSV57647546; called by muse, mutect2, varscan2
- TMEM131L | c.4271C>G p.T1424S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53643008, COSV53651423; called by muse, mutect2, varscan2
- TMEM150C | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV71388873; called by muse, mutect2, varscan2
- TMOD3 | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57943204; called by muse, mutect2, varscan2
- TMPRSS2 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as COSV59822645; called by muse, mutect2
- TMTC3 | c.1221G>A p.W407* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as rs1417145000, COSV99898657; called by muse, mutect2, varscan2
- TOR1B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1475083915, COSV52212932; called by muse, mutect2, varscan2
- TP53BP2 | c.2324C>G p.S775* (on ENST00000343537 / NM_001031685.3; = p.S646* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 85/91 reads (93%) | catalogued as COSV59068410; called by muse, mutect2, varscan2
- TRA2B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1254689753, COSV52025033; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1387-1G>A p.X463_splice | Splice Site (SNP) | VAF 20/89 reads (22%) | catalogued as COSV60675523; called by muse, mutect2, varscan2
- TRANK1 | c.7093C>A p.L2365I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57146648; called by muse, mutect2, varscan2
- TRIM33 | c.3148G>C p.D1050H | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV61821936; called by muse, mutect2, varscan2
- TRIO | c.7990G>C p.E2664Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV59989724; called by muse, mutect2, varscan2
- TRIOBP | c.6614T>A p.L2205Q (on ENST00000644935 / NM_001039141.3; = p.L492Q on NM_007032.5) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60375939; called by muse, mutect2, varscan2
- TRMT1L | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV62254288; called by muse, mutect2, varscan2
- TSHZ2 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV61588000; called by muse, mutect2, varscan2
- TTN | c.84944C>G p.P28315R (on ENST00000591111; = p.P20891R on NM_003319.4) | Missense Mutation (SNP) | VAF 23/26 reads (88%) | PolyPhen benign (0.414); catalogued as COSV59984854; called by muse, mutect2, varscan2
- TUBD1 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs1350676244, COSV57872485; called by muse, mutect2, varscan2
- TXNDC5 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65730253; called by muse, mutect2, varscan2
- UBA7 | c.1852_1869del p.E618_F623del | In Frame Del (DEL) | VAF 32/105 reads (30%) | catalogued as COSV60967437; called by mutect2, pindel
- UBR2 | c.5264T>A p.L1755* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100867516, COSV65750985; called by muse, mutect2, varscan2
- UNC93A | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs748663025, COSV57807652, COSV57807994; called by muse, mutect2, varscan2
- UPF3A | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 85/131 reads (65%) | catalogued as COSV100677719; called by muse, mutect2, varscan2
- UPK1A | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99721925, COSV99722065; called by muse, mutect2, varscan2
- USP19 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs998900096, COSV60045592; called by muse, mutect2, varscan2
- VAV2 | c.913G>A p.E305K (on ENST00000371850 / NM_001134398.2; = p.E300K on NM_003371.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV64081278; called by muse, mutect2, varscan2
- VCAM1 | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as COSV54121763, COSV99658900; called by muse, mutect2, varscan2
- VEZT | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755091384, COSV54137628; called by muse, mutect2, varscan2
- VTA1 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs766615371, COSV62658610; called by muse, mutect2, varscan2
- WDR48 | c.430T>C p.W144R | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56531353; called by muse, mutect2, varscan2
- WEE1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV55196822; called by muse, mutect2, varscan2
- WIPF2 | c.380T>A p.V127E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV60273188; called by muse, mutect2, varscan2
- ZFYVE9 | c.1424C>G p.S475C | Missense Mutation (SNP) | VAF 78/115 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV55092639; called by muse, mutect2, varscan2
- ZFYVE9 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55092646, COSV99819996; called by muse, mutect2, varscan2
- ZIC1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV51552014, COSV51555391; called by muse, mutect2
- ZMYM1 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV63251458; called by muse, mutect2, varscan2
- ZMYND15 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 82/91 reads (90%) | catalogued as COSV52639458, COSV99351788; called by muse, mutect2, varscan2
- ZNF106 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55515512, COSV99782238; called by muse, mutect2
- ZNF189 | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1469718653, COSV52274947; called by muse, mutect2, varscan2
- ZNF25 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56922166, COSV56922873; called by muse, mutect2, varscan2
- ZNF26 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1490351584; called by muse, mutect2, varscan2
- ZNF318 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750972209, COSV58931653; called by muse, mutect2, varscan2
- ZNF318 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV58931671; called by muse, mutect2, varscan2
- ZNF45 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as COSV54192846; called by muse, mutect2
- ZNF507 | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 25/41 reads (61%) | catalogued as COSV100322045; called by muse, mutect2, varscan2
- ZNF511 | c.430-1G>T p.X144_splice | Splice Site (SNP) | VAF 72/96 reads (75%) | catalogued as COSV62919920; called by muse, mutect2, varscan2
- ZNF607 | c.497G>C p.R166P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs750129424, COSV62206576, COSV67696619; called by muse, mutect2, varscan2
- ZNF619 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59029760; called by muse, mutect2, varscan2
- ZNF671 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.879); catalogued as COSV58052315; called by muse, mutect2, varscan2
- ZNF684 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.061); catalogued as COSV65518951, COSV65519474; called by muse, mutect2, varscan2
- ZNF804A | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs774780722, COSV56435058, COSV56443981; called by muse, mutect2, varscan2
- ZNF804B | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV60823585; called by muse, mutect2, varscan2
- ZNF91 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV56083236; called by muse, mutect2
- ACACA | c.6598G>C p.E2200Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- AEBP2 | c.838_842del p.D280Hfs*22 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- AFDN | c.3074del p.A1025Efs*9 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- AKR1C8P | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BOP1 | c.2178C>G p.F726L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYRIB | c.4_29del p.G2Hfs*4 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel
- FCGBP | c.7198C>T p.P2400S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GPR179 | c.5229G>C p.E1743D (on ENST00000621958; = p.E1742D on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- LPA | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MYO9A | c.62_74del p.Y21Ffs*21 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel
- PPM1G | c.729_742del p.D246Sfs*3 | Frame Shift Del (DEL) | VAF 42/65 reads (65%) | called by mutect2, pindel, varscan2
- RUNX1 | c.729_742del p.R244Ifs*324 (on ENST00000344691 / NM_001001890.3; = p.R271Ifs*324 on NM_001754.5) | Frame Shift Del (DEL) | VAF 52/73 reads (71%) | called by mutect2, pindel, varscan2
- SLC38A2 | c.214del p.S72Pfs*9 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | called by mutect2, pindel, varscan2
- SPO11 | c.239del p.N80Tfs*2 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel
- TEP1 | c.133_134insGAATATCC p.L45Rfs*6 | Frame Shift Ins (INS) | VAF 26/40 reads (65%) | called by mutect2, pindel, varscan2
- TMEM169 | c.421del p.E141Kfs*25 | Frame Shift Del (DEL) | VAF 30/45 reads (67%) | called by mutect2, pindel, varscan2
- TNPO1 | c.1833_1844del p.Y612_P615del | In Frame Del (DEL) | VAF 50/133 reads (38%) | called by mutect2, pindel, varscan2
- TRIO | c.2523_2527del p.L841Ffs*2 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- UNC13B | c.4590_4607del p.M1531_V1536del | In Frame Del (DEL) | VAF 20/37 reads (54%) | called by mutect2, pindel, varscan2
- USP10 | c.1555-14_1563delinsG p.X519_splice | Splice Site (DEL) | VAF 27/74 reads (36%) | called by pindel, varscan2*
- UTP20 | c.8003_8018del p.P2668Lfs*17 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- XRCC3 | c.562-1_566dup p.D188_T189dup | In Frame Ins (INS) | VAF 18/21 reads (86%) | called by mutect2, pindel
- ZFYVE26 | c.878_886+25del p.X293_splice | Splice Site (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- ZNF408 | c.865_873del p.G289_S291del | In Frame Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.4635G>T p.S1545= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs745869372, COSV55778765; called by muse, mutect2, varscan2
- ADAT1 | c.129A>T p.P43= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV57186115; called by muse, mutect2, varscan2
- ADGRG5 | c.642C>G p.P214= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV61082995; called by muse, mutect2, varscan2
- ADGRV1 | c.13510A>C p.R4504= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV101316447, COSV67978378; called by muse, mutect2, varscan2
- ANO8 | c.1167G>A p.K389= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV50175212; called by muse, mutect2, varscan2
- ANXA13 | c.204C>G p.L68= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV51622504; called by muse, mutect2, varscan2
- ANXA8 | c.606C>T p.I202= | Silent (SNP) | VAF 24/127 reads (19%) | called by muse, varscan2
- AOC2 | c.240G>T p.V80= | Silent (SNP) | VAF 79/163 reads (48%) | catalogued as COSV53198755; called by muse, mutect2, varscan2
- APOL1 | c.1155C>T p.L385= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV59868804; called by muse, mutect2, varscan2
- APOL4 | c.426C>T p.I142= (on ENST00000352371 / NM_145660.2; = p.I139= on NM_030643.4) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs768034738, COSV60654345; called by muse, mutect2, varscan2
- ARCN1 | c.159T>C p.S53= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs1555074588, COSV50614691; called by muse, mutect2, varscan2
- ASZ1 | c.772T>C p.L258= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV52912358, COSV99498151; called by muse, mutect2, varscan2
- ATP10A | c.2379G>C p.R793= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV63515975; called by muse, mutect2, varscan2
- ATP10A | c.303G>A p.P101= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs778050331, COSV63515978; called by muse, mutect2, varscan2
- BACE2 | c.1284C>T p.F428= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs180759114, COSV57737784; called by muse, mutect2
- BCHE | c.1254T>G p.G418= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV52255530, COSV52257580; called by muse, mutect2
- BRD1 | c.936C>T p.I312= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs771198220, COSV53456260; called by muse, mutect2, varscan2
- C12orf56 | c.73C>T p.L25= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs377465987, COSV61486431, COSV61489111; called by muse, mutect2, varscan2
- C19orf53 | c.123G>T p.A41= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV50004102; called by muse, mutect2, varscan2
- C4BPA | c.1149T>G p.P383= | Silent (SNP) | VAF 106/114 reads (93%) | catalogued as COSV65536177; called by muse, mutect2, varscan2
- C6 | c.1908T>A p.P636= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV54708482; called by muse, mutect2, varscan2
- CBWD1 | c.927C>T p.H309= | Silent (SNP) | VAF 5/34 reads (15%) | called by mutect2, varscan2
- CEBPE | c.564C>G p.S188= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52829496; called by muse, mutect2, varscan2
- CHMP4B | c.126C>T p.F42= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs745654601, COSV54134883; called by muse, mutect2
- CLDN2 | c.450A>G p.P150= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as COSV61020754; called by muse, mutect2, varscan2
- CLN8 | c.619C>T p.L207= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV58670193; called by muse, mutect2, varscan2
- CNTNAP1 | c.1395G>C p.G465= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV52849274; called by muse, mutect2, varscan2
- COL24A1 | c.1461G>C p.L487= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65304766; called by muse, mutect2, varscan2
- COL6A6 | c.6147C>T p.H2049= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs761592897, COSV62022289; called by muse, mutect2, varscan2
- CROT | c.606C>G p.V202= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV58973756; called by muse, mutect2, varscan2
- CSRNP2 | c.453C>G p.G151= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV57334088; called by muse, mutect2, varscan2
- CTSH | c.687C>T p.A229= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as rs766353740, COSV54984626; called by muse, mutect2, varscan2
- DAPK1 | c.2946C>G p.P982= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV63786520; called by muse, mutect2, varscan2
- DCAF8L1 | c.1287G>A p.K429= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV71595211; called by muse, mutect2, varscan2
- DCDC1 | c.4437G>A p.Q1479= (on ENST00000597505 / NM_001367979.1; = p.Q586= on NM_020869.3) | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100338752; called by muse, mutect2
- DENND1C | c.1716G>A p.K572= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57568358; called by muse, mutect2, varscan2
- DPAGT1 | c.1212C>G p.L404= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV53828135; called by muse, mutect2
- DST | c.6345A>C p.I2115= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV55008104; called by muse, mutect2, varscan2
- EFHD2 | c.156C>T p.D52= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV101044496; called by mutect2, varscan2
- ERCC3 | c.1842G>A p.S614= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs750922401, COSV53426618; called by muse, mutect2, varscan2
- ERN2 | c.190C>T p.L64= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV56832786; called by muse, mutect2, varscan2
- FBN3 | c.1434C>T p.F478= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV54457985; called by muse, mutect2, varscan2
- FMNL1 | c.927G>A p.L309= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV58956402; called by muse, mutect2, varscan2
- FN1 | c.1884C>T p.I628= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as COSV60550264; called by muse, mutect2, varscan2
- FRY | c.1005C>G p.P335= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV66568307; called by muse, mutect2, varscan2
- FUT4 | c.1266C>T p.I422= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV62469187; called by muse, mutect2, varscan2
- GALNT11 | c.1737G>A p.L579= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV57424362; called by muse, mutect2, varscan2
- GALNT8 | c.933T>G p.R311= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52896564; called by muse, mutect2, varscan2
- GART | c.2910A>C p.A970= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV67818411; called by muse, mutect2, varscan2
- GNPDA2 | c.60C>T p.I20= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV54946437; called by muse, mutect2, varscan2
- GRM5 | c.2460G>A p.P820= | Silent (SNP) | VAF 49/87 reads (56%) | catalogued as rs768641882, COSV104398484, COSV59600175; called by muse, mutect2, varscan2
- HEATR6 | c.928C>A p.R310= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV51744812, COSV51747477; called by muse, mutect2, varscan2
- HEG1 | c.3972C>T p.L1324= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV60761044; called by mutect2, varscan2
- HFM1 | c.3417G>C p.G1139= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as COSV54025407; called by muse, mutect2, varscan2
- HIVEP2 | c.6798G>A p.A2266= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as rs755189879, COSV50008575; called by muse, mutect2, varscan2
- HJV | c.1257T>C p.F419= (on ENST00000336751 / NM_213653.4; = p.F306= on NM_145277.5) | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV60951715; called by muse, mutect2, varscan2
- HLA-C | c.258G>C p.R86= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs61759940, COSV66112195; called by muse, mutect2, varscan2
- IL27 | c.456C>G p.R152= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV60489903; called by muse, mutect2, varscan2
- IMPA2 | c.471C>T p.L157= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs758269140, COSV52319304; called by muse, mutect2, varscan2
- INO80 | c.2598A>T p.P866= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV62737329; called by muse, mutect2, varscan2
- IQUB | c.2097C>G p.V699= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as COSV61238584; called by muse, mutect2, varscan2
- ITGB4 | c.1059C>G p.S353= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV52324339; called by muse, mutect2, varscan2
- JPT2 | c.252G>C p.L84= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV50188688; called by muse, mutect2, varscan2
- KCMF1 | c.804A>G p.T268= | Silent (SNP) | VAF 26/27 reads (96%) | catalogued as COSV69053531; called by muse, mutect2, varscan2
- KIAA1191 | c.72C>T p.I24= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as rs765051317, COSV53798741; called by muse, mutect2, varscan2
- KIF15 | c.3129G>C p.L1043= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV58159821; called by muse, mutect2, varscan2
- KRT85 | c.516C>T p.F172= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV57736503; called by muse, mutect2, varscan2
- LPCAT4 | c.870G>A p.Q290= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1314859694, COSV59216464; called by muse, mutect2, varscan2
- LRP1 | c.1728C>T p.A576= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs566214120, COSV54507552, COSV54527706; called by muse, mutect2, varscan2
- MMP7 | c.435G>A p.R145= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV52771785; called by muse, mutect2, varscan2
- MYO18B | c.618C>G p.T206= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100125042; called by muse, varscan2
- NCOA5 | c.246G>C p.R82= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV51643737; called by muse, mutect2, varscan2
- NPHP4 | c.609T>G p.P203= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV65393786, COSV65394341; called by muse, mutect2, varscan2
- OPLAH | c.2496G>C p.L832= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101470923; called by muse, mutect2, varscan2
- PCBD2 | c.312C>T p.L104= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV54736932; called by muse, mutect2, varscan2
- PCDH10 | c.2202C>T p.I734= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1237235074, COSV52091578; called by muse, mutect2, varscan2
- PCYOX1L | c.354C>T p.F118= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs963086858, COSV51002361; called by muse, varscan2
- PLEKHO1 | c.216G>C p.L72= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as COSV50310034; called by muse, mutect2, varscan2
- PLG | c.2175G>A p.E725= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57513626, COSV57514666; called by muse, mutect2, varscan2
- PLK3 | c.276C>T p.V92= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs779221301, COSV100943738; called by muse, varscan2
- PRAMEF1 | c.75C>A p.I25= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV60008136; called by muse, mutect2, varscan2
- PRAMEF14 | c.75C>A p.I25= | Silent (SNP) | VAF 31/153 reads (20%) | called by muse, varscan2
- PRDM4 | c.2250A>G p.K750= | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as COSV57305346; called by muse, mutect2, varscan2
- PRDM9 | c.1542G>C p.V514= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV57004957, COSV57014674; called by muse, mutect2, varscan2
- PRKCD | c.138G>A p.Q46= | Silent (SNP) | VAF 55/61 reads (90%) | catalogued as COSV57847732; called by muse, mutect2, varscan2
- PRSS16 | c.132C>A p.G44= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1405887257, COSV57915264; called by muse, mutect2, varscan2
- PSTK | c.60C>G p.L20= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100924795; called by muse, varscan2
- PTHLH | c.387G>A p.K129= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV52367295; called by muse, mutect2, varscan2
- PTX3 | c.597G>A p.V199= | Silent (SNP) | VAF 78/104 reads (75%) | catalogued as COSV55821489; called by muse, mutect2, varscan2
- RASGRF2 | c.2526G>A p.A842= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs755800361, COSV54127393; called by muse, mutect2, varscan2
- RELCH | c.126C>G p.G42= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV56884272; called by muse, mutect2, varscan2
- RERE | c.4677G>A p.K1559= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as rs756416420, COSV61940610; called by muse, mutect2, varscan2
- RGS22 | c.2295T>C p.Y765= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV62660305; called by muse, mutect2, varscan2
- RIN1 | c.867G>A p.R289= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1272228554, COSV100254948; called by muse, mutect2, varscan2
- RIPOR3 | c.2277C>T p.I759= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1367285418, COSV50387389; called by muse, mutect2, varscan2
- RMND5B | c.958T>C p.L320= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV51070915; called by muse, mutect2, varscan2
- RPGRIP1 | c.969C>G p.L323= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as rs775426540, COSV52845448; called by muse, varscan2
- RPL3L | c.1053C>G p.L351= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1329606516, COSV51906093; called by muse, mutect2, varscan2
- RPS6KA1 | c.1707G>T p.G569= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100943018, COSV65175916; called by muse, mutect2, varscan2
- RYK | c.1621C>T p.L541= (on ENST00000620660 / NM_001005861.2; = p.L538= on NM_002958.4) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56061712, COSV56062068, COSV99938639; called by muse, mutect2, varscan2
- SACM1L | c.1329T>C p.N443= | Silent (SNP) | VAF 59/62 reads (95%) | catalogued as COSV66612971; called by muse, mutect2, varscan2
- SCAF8 | c.1992G>A p.P664= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs775295404, COSV63200190; called by muse, mutect2, varscan2
- SCMH1 | c.1305C>T p.L435= (on ENST00000326197 / NM_001031694.2; = p.L388= on NM_012236.4) | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV58234272; called by muse, mutect2, varscan2
- SCUBE1 | c.2604C>G p.T868= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs770618250, COSV62611529; called by muse, mutect2, varscan2
- SDK1 | c.837G>A p.L279= | Silent (SNP) | VAF 61/78 reads (78%) | catalogued as COSV67363954; called by muse, mutect2, varscan2
- SETD1A | c.3069A>T p.S1023= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV52686692; called by muse, mutect2, varscan2
- SLC16A9 | c.945C>T p.L315= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs370684670; called by muse, mutect2, varscan2
- SLC29A1 | c.228C>T p.L76= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs1471066771, COSV57577945; called by muse, mutect2, varscan2
- SLC7A8 | c.1218G>A p.Q406= | Silent (SNP) | VAF 100/105 reads (95%) | catalogued as COSV57553693; called by muse, mutect2, varscan2
- SLC8B1 | c.177G>C p.L59= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as rs1395628697, COSV52527275; called by muse, mutect2, varscan2
- SLC9A2 | c.867C>A p.G289= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV52130880; called by muse, mutect2, varscan2
- SLCO5A1 | c.1347T>G p.T449= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV52657373; called by muse, mutect2, varscan2
- SP3 | c.1893C>G p.V631= | Silent (SNP) | VAF 40/44 reads (91%) | catalogued as COSV59467079; called by muse, mutect2, varscan2
- STAC | c.621C>T p.T207= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV56209039; called by muse, mutect2, varscan2
- STAC3 | c.798G>C p.L266= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV60414034; called by muse, mutect2, varscan2
- STIP1 | c.1551A>T p.A517= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99656790; called by muse, mutect2
- TARDBP | c.408G>A p.K136= | Silent (SNP) | VAF 66/97 reads (68%) | catalogued as COSV53569548; called by muse, mutect2, varscan2
- TBX18 | c.72G>A p.A24= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1161844753, COSV63736579; called by muse, mutect2, varscan2
- TBXT | c.708C>T p.S236= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV51617134; called by muse, mutect2, varscan2
- TDRD7 | c.105T>A p.T35= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV62429067; called by muse, mutect2, varscan2
- TMED5 | c.318C>T p.F106= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs375076920; called by muse, mutect2, varscan2
- TNPO2 | c.1608C>T p.L536= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs767191919, COSV63508001; called by muse, mutect2, varscan2
- TNRC6A | c.3459T>C p.N1153= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV59362965; called by muse, mutect2, varscan2
- TSNARE1 | c.552G>T p.L184= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56173989; called by muse, mutect2, varscan2
- U2AF2 | c.369C>T p.P123= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58273290; called by muse, mutect2, varscan2
- UNC119 | c.597C>T p.L199= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV56378782; called by muse, mutect2, varscan2
- WDR37 | c.675C>T p.I225= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs770901554, COSV54128118; called by muse, mutect2, varscan2
- WSCD2 | c.1029C>T p.L343= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54580910; called by muse, mutect2, varscan2
- ZFAND2B | c.471T>G p.S157= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV54694788; called by muse, mutect2, varscan2
- ZMIZ1 | c.828C>T p.F276= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs747270716, COSV57893217; called by muse, mutect2, varscan2
- ZNF28 | c.1896G>A p.E632= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as COSV60422719, COSV60422841; called by muse, mutect2, varscan2
- ZNF513 | c.186C>T p.L62= | Silent (SNP) | VAF 145/158 reads (92%) | catalogued as COSV52007295; called by muse, mutect2, varscan2
- ZSWIM4 | c.2355C>T p.F785= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs781050746, COSV54320750; called by muse, mutect2, varscan2
- AL136295.1 | c.-12G>C | 5'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as COSV51660035; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503711 del TCTTCTCTAA | 5'Flank (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65500781 C>T | 5'Flank (SNP) | VAF 6/39 reads (15%) | catalogued as rs1433659247; called by muse, mutect2
- AP000769.5 | chr11:65500946 del GTCTGAAGCTTTTGA | 5'Flank (DEL) | VAF 42/55 reads (76%) | called by mutect2, pindel, varscan2
- C9orf106 | n.690C>G | RNA (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- CDCA7 | c.147+461T>C | Intron (SNP) | VAF 45/47 reads (96%) | catalogued as COSV60720204; called by muse, mutect2, varscan2
- CDK15 | c.1009+5853T>C | Intron (SNP) | VAF 33/35 reads (94%) | catalogued as rs1320942625, COSV99643664; called by muse, mutect2, varscan2
- CUL4A | chr13:113208611 C>T | 5'Flank (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99872643; called by muse, mutect2
- DELEC1 | n.705C>G | RNA (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100927075; called by muse, varscan2
- IGKV2OR22-4 | n.11C>A | RNA (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- MIR1-1 | n.62A>G | RNA (SNP) | VAF 159/169 reads (94%) | catalogued as rs1555902770; called by muse, mutect2, varscan2
- NRG1 | c.1269-437C>A | Intron (SNP) | VAF 19/79 reads (24%) | catalogued as rs773199629, COSV55154759; called by muse, mutect2, varscan2
- SH2D6 | n.361C>T | RNA (SNP) | VAF 41/47 reads (87%) | catalogued as rs781760373, COSV61063765; called by muse, mutect2, varscan2
- STMP1 | chr7:135660249 C>G | 5'Flank (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
